Gene-level copy-number profile of tumor specimen TCGA-OR-A5K6-01A from TCGA case TCGA-OR-A5K6, project TCGA-ACC (Adrenocortical Carcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Adrenal cortical carcinoma; Tissue or organ of origin: Cortex of adrenal gland; Age at diagnosis: 56.6 years (20,657 days).
Specimen TCGA-OR-A5K6-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-ACC.95e23d17-a163-464b-a166-59835b0a1e28.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-OR-A5K6-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 815 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; AscatNGS; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/bd7abca2-92e6-4b79-afb2-f99c9cad5f6f

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 1: 7,921; copy number 2: 50,547; copy number 3: 742; copy number 4: 142; copy number 5: 211; copy number 6: 239; copy number 7: 6.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-OR-A5K6-01A-11D-A29H-01): tumor purity 0.91, ploidy 1.91, whole-genome doublings 0.

Homozygous deletions (total copy number 0; autosomes only): none.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 456 genes in 6 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr7:19,918,981–20,221,700, 6 genes, copy number 7 (within-gene range 4–7): AC005062.1, RPL21P75, AC007001.1, MACC1, MACC1-AS1, AC005083.1.
- chr7:38,256,337–38,322,730, 11 genes, copy number 5: TRGJP2, TRGC1, TRGJ1, TRGJP, TRGJP1, TRGV11, TRGVB, TRGV10, AC006033.1, TRGV9, TRGVA.
- chr7:87,503,017–99,050,831, 183 genes, copy number 6 (within-gene range 3–6) (broad region; genes not listed).
- chr7:99,392,048–102,464,863, 159 genes, copy number 5 (within-gene range 1–5) (broad region; genes not listed).
- chr17:79,707,266–80,966,371, 41 genes, copy number 5 (within-gene range 3–5): LINC02078, ENPP7, CBX2, CBX8, AC100791.2, LINC01977, CBX4, AC100791.1, LINC01979, LINC01978, TBC1D16, AC100791.3, AC116025.2, AC116025.1, CCDC40, MIR1268B, GAA, EIF4A3, AC087741.3, AC087741.2, CARD14, AC087741.1, SGSH, SLC26A11, RNF213, AC124319.1, AC124319.2, AC124319.3, RNF213-AS1, ENDOV, MIR4730, AC120024.1, AC120024.4, NPTX1, AC120024.2, AC120024.3, RPL32P31, RPTOR, RPL31P7, AC016245.1, AC016245.2.
- chr17:81,701,324–82,375,586, 56 genes, copy number 6: AC139530.1, MRPL12, AC139530.2, SLC25A10, GCGR, MCRIP1, PPP1R27, P4HB, AC145207.3, AC145207.9, AC145207.2, ARHGDIA, AC145207.5, AC145207.6, ALYREF, ANAPC11, NPB, PCYT2, SIRT7, MAFG, AC145207.8, MAFG-DT, PYCR1, AC145207.4, MYADML2, AC145207.1, NOTUM, AC145207.7, ASPSCR1, CENPX, LRRC45, RAC3, DCXR, AC137723.1, DCXR-DT, RFNG, GPS1, DUS1L, FASN, CCDC57, AC129510.1, AC129510.2, AC132872.2, SLC16A3, MIR6787, CSNK1D, AC132872.3, AC132872.4, AC132872.5, LINC01970, AC132872.1, CD7, SECTM1, TEX19, AC132938.4, UTS2R.

Autosomal genes at a single copy (total copy number 1): 7,921. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
